Somatic mutation profile of tumor specimen TARGET-30-PARCRR-01A (aliquot TARGET-30-PARCRR-01A-01D) from TARGET case TARGET-30-PARCRR, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.8 years (1,742 days).
Specimen TARGET-30-PARCRR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64fe4c09-28f2-41b8-9bad-52c1e3c5bc9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARCRR-10A (Blood Derived Normal), aliquot TARGET-30-PARCRR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/214af45c-b476-4bdc-935c-ec3d38843aa1

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH1A1 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV52795050; called by muse, mutect2, varscan2
- APOM | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.393); catalogued as rs1271130582, COSV52996141; called by muse, mutect2, varscan2
- CD22 | c.2184G>T p.Q728H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50049566, COSV50074338; called by muse, mutect2, varscan2
- HRH4 | c.1010C>A p.S337* | Nonsense Mutation (SNP) | VAF 12/218 reads (6%) | catalogued as rs1248799304; called by muse, mutect2
- LENG1 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55369300; called by muse, mutect2, varscan2
- NLRP12 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 118/596 reads (20%) | catalogued as COSV60756920; called by muse, mutect2, varscan2
- NXPE1 | c.482A>G p.N161S (on ENST00000424269; = p.N19S on NM_152315.5) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52634105; called by muse, mutect2, varscan2
- PDE4DIP | c.6723C>G p.H2241Q | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100519012, COSV57725779, COSV57734296; called by muse, mutect2, varscan2
- PLCB1 | c.3370C>T p.L1124F | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62071771; called by muse, mutect2, varscan2
- MAD2L1BP | c.66G>A p.K22= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV64679658; called by muse, mutect2, varscan2
- PLXND1 | c.2667C>T p.P889= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs147290514; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+662G>T | Intron (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
